Somatic mutation profile of tumor specimen 0DQZ4B from CCDI case PBCFKX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.2 years (3,719 days).
Specimen 0DQZ4B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ce77bc7-472f-43bd-af2f-3af8688276c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQZ3D (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a1ba892-fddb-4d56-8129-31d98127898f

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, 5'Flank 3, Frame Shift Del 3, Intron 2, Silent 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 144/261 reads (55%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.5295_5296del p.A1767Rfs*14 (on ENST00000358273 / NM_001042492.3; = p.A1746Rfs*14 on NM_000267.3) | Frame Shift Del (DEL) | VAF 178/260 reads (68%) | catalogued as rs1555533552; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PPM1D | c.1451T>G p.L484* | Nonsense Mutation (SNP) | VAF 468/766 reads (61%) | catalogued as rs766524048, CD132017, CM131997, COSV100010613, COSV59954652, COSV59957436; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BTC | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs140634211; called by muse, mutect2
- CASR | c.2680G>A p.G894S (on ENST00000490131; = p.G971S on NM_000388.4) | Missense Mutation (SNP) | VAF 317/566 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56135532; called by muse, mutect2, varscan2
- CBL | c.1193A>C p.H398P | Missense Mutation (SNP) | VAF 75/110 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1303812580, CM105461, COSV50630308, COSV50662103; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL12A1 | c.5857C>T p.R1953C | Missense Mutation (SNP) | VAF 140/308 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs777948762, COSV59393496; called by muse, mutect2, varscan2
- EBF2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 157/210 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369154726; called by muse, mutect2, varscan2
- FAM83H | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 142/320 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs202111118; called by muse, mutect2, varscan2
- H1-5 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 106/274 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58900487, COSV58900522; called by muse, mutect2, varscan2
- ZNF831 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 55/376 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs773723423; called by muse, mutect2, varscan2
- ADAMTS19 | c.2611del p.L871Sfs*82 | Frame Shift Del (DEL) | VAF 141/386 reads (37%) | called by mutect2, pindel, varscan2
- ATRX | c.5335_5338del p.R1779Lfs*2 | Frame Shift Del (DEL) | VAF 125/142 reads (88%) | called by mutect2, pindel, varscan2
- COL1A1 | c.899A>C p.Q300P | Missense Mutation (SNP) | VAF 149/490 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- NPFFR1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TRIM62 | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 142/303 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- RASGRF2 | c.3312C>T p.A1104= | Silent (SNP) | VAF 212/501 reads (42%) | called by muse, mutect2, varscan2
- ABCD4 | c.285+67G>A | Intron (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- CLBA1 | c.569+55T>C | Intron (SNP) | VAF 36/105 reads (34%) | catalogued as rs961487437; called by muse, mutect2, varscan2
- DNAJC5G | chr2:27275305 C>G | 5'Flank (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- PARP11 | c.*9C>T | 3'UTR (SNP) | VAF 84/190 reads (44%) | called by muse, mutect2, varscan2
- RNU1-143P | chr1:143796038 C>T | 5'Flank (SNP) | VAF 51/309 reads (17%) | catalogued as rs1397383784; called by muse, mutect2, varscan2
- SERINC2 | chr1:31410308 T>G | 5'Flank (SNP) | VAF 8/24 reads (33%) | called by muse, varscan2
